Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96I, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96I-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor diameter: 4.2 cm

Diagnosis:

Type A/B-Thymoma

pT3, pNx

Masaoka: III

infiltration of mediastinal fat tissue and lung parenchyma

Immunohistochemistry

epithelial cells positive for: CK 5/6

epithelial cells negative for: CD1a, CD5, CD117

in between epithelial cells CD5-positive mature T-lymphocytes

ICD-O-3

Thymoma, type A/B
malignant 8582/3

Site Anterior mediastinum
C38.1

JW 4/7/14

Source: NCI Genomic Data Commons file 24ace4ad-5963-40ec-b3d4-f002d2b88475 (TCGA-ZB-A96I.FA6DC0F4-E9F6-4E35-BC7F-E87036CD34D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).